Somatic mutation profile of tumor specimen TCGA-FY-A76V-01A (aliquot TCGA-FY-A76V-01A-11D-A397-08) from TCGA case TCGA-FY-A76V, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 54.4 years (19,872 days).
Specimen TCGA-FY-A76V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 305a8b4c-42a6-4f64-9071-1e923334baac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A76V-10A (Blood Derived Normal), aliquot TCGA-FY-A76V-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe8330df-89d9-4913-abdf-5b2d125ab7ed

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.303_308del p.E102_I103del | In Frame Del (DEL) | VAF 23/64 reads (36%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ARHGAP4 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 48/64 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV100604069; called by muse, mutect2, varscan2
- BPIFB6 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100848521; called by muse, mutect2
- CDK14 | c.1018G>C p.D340H (on ENST00000380050 / NM_001287135.2; = p.D322H on NM_012395.3) | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56035765, COSV99724294; called by muse, mutect2
- CLCA4 | c.869C>T p.T290I | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.194); catalogued as COSV99760539; called by muse, mutect2, varscan2
- DPY19L2 | c.1623G>T p.L541F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); catalogued as COSV100193498; called by muse, mutect2, varscan2
- NDUFA9 | c.382A>T p.N128Y | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99865708; called by muse, mutect2, varscan2
- RYR1 | c.9858G>C p.E3286D | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV100615852; called by muse, mutect2, varscan2
- ASB15 | c.54G>A p.Q18= | Silent (SNP) | VAF 12/275 reads (4%) | catalogued as COSV99306598; called by muse, mutect2
- NAIF1 | c.831C>G p.G277= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV100895801; called by muse, mutect2, varscan2
